Somatic mutation profile of tumor specimen TCGA-XJ-A83H-01A (aliquot TCGA-XJ-A83H-01A-11D-A34U-08) from TCGA case TCGA-XJ-A83H, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A83H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88acc559-b033-45be-bd8f-6fde707a2ef9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A83H-10A (Blood Derived Normal), aliquot TCGA-XJ-A83H-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69b66ca3-ec1c-49d8-96b1-e821eb47eb85

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.5542G>A p.D1848N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs188078418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEBPE | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs777425212, COSV99247348; called by muse, mutect2, varscan2
- CUL9 | c.5725G>C p.G1909R | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.127); catalogued as COSV99334833; called by muse, mutect2, varscan2
- CYGB | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99505965; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 33/129 reads (26%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- EIF3B | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.142); catalogued as rs139537965; called by muse, mutect2
- FBN2 | c.4631A>G p.N1544S | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as rs1399453739, COSV99325180; called by muse, mutect2
- HMGB2 | c.588_593del p.E196_E197del | In Frame Del (DEL) | VAF 20/96 reads (21%) | catalogued as rs761460501; called by mutect2, pindel, varscan2
- IFT140 | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100794153; called by muse, mutect2, varscan2
- IL17RB | c.811T>G p.C271G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99861023; called by muse, mutect2
- KANK2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs201517586, COSV100763039; called by muse, mutect2, varscan2
- MIEF1 | c.322+1G>C p.X108_splice | Splice Site (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100307542, COSV57479198; called by muse, mutect2
- NID2 | c.3502C>T p.R1168C | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs117206856; called by muse, mutect2, varscan2
- OR5T1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100478745; called by muse, mutect2, varscan2
- RAPGEF6 | c.2324A>G p.E775G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs780537141, COSV99725400; called by muse, mutect2, varscan2
- SLC26A4 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV55915916, COSV99706573; called by muse, mutect2
- TEX14 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs374732278, COSV53615912; called by muse, mutect2, varscan2
- TMEM131L | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV53641244, COSV53644528; called by muse, mutect2
- UBE4A | c.2267G>T p.W756L (on ENST00000252108 / NM_001204077.2; = p.W763L on NM_004788.4) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201356695, COSV52806388; called by muse, mutect2, varscan2
- ZNF664 | c.143T>G p.I48S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.122); catalogued as COSV100544382; called by muse, mutect2, varscan2
- CCDC80 | c.2685G>A p.S895= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs768070081, COSV99244323; called by muse, mutect2, varscan2
- HMGCS1 | c.1251T>A p.G417= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV100284908; called by muse, mutect2
- MTNR1A | c.480G>A p.L160= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs1401204102, COSV100208088; called by muse, mutect2, varscan2
- NOTCH4 | c.2589G>T p.G863= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs763133141, COSV100900386; called by muse, mutect2
- SLC25A12 | c.1302C>T p.G434= | Silent (SNP) | VAF 7/153 reads (5%) | catalogued as rs1451768338, COSV99784699; called by muse, mutect2
- ZNF202 | c.1248G>T p.L416= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV100278919; called by muse, mutect2, varscan2
